Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BX, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BX-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with left retroperitoneal sarcoma.

Specimens Submitted:

- 1: SP: Radical resection left retroperitoneal sarcoma
- 2: SP: Final deep quadratus and psoas margin

DIAGNOSIS:

1. SOFT TISSUE, LEFT RETROPERITONEAL SARCOMA; LEFT KIDNEY, LEFT URETER, LEFT ADRENAL GLAND; LARGE BOWEL, DESCENDING COLON; RADICAL RESECTION:
- HIGH GRADE SARCOMA. (SEE NOTE.)
- SIZE: 27.5 CM.
- ANATOMIC INVOLVEMENT: RETROPERITONEAL FIBROADIPOSE TISSUE , SKELETAL MUSCLE, RENAL PARENCHYMA, AND THE WALL OF THE DESCENDING COLON.
- NECROSIS: PROMINENT (APPROXIMATELY TWO THIRDS OF THE TUMOR, MEASURED GROSSLY).
- MITOTIC RATE: 65 MIT./10 HPF.
- THE TUMOR EXTENDS TO LATERAL, MEDIAL, ANTERIOR AND POSTERIOR MARGINS.
- THE KIDNEY PARENCHYMA IS UNREMARKABLE.
- THE RENAL VASCULAR AND URETERIC MARGINS ARE NEGATIVE FOR TUMOR.
- BENIGN ADRENAL GLAND, NEGATIVE FOR TUMOR.
- THE COLONIC MUCOSA IS UNREMARKABLE.
- THE COLONIC SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- OMENTUM, NEGATIVE FOR TUMOR.
- EIGHT BENIGN LYMPH NODES.
2. SKELETAL MUSCLE, FINAL DEEP QUADRATUS AND PSOAS MARGIN; EXCISION:
- SARCOMA INVOLVING SKELETAL MUSCLE AND FIBROADIPOSE TISSUE.
- TUMOR IS PRESENT AT A BLACK-INKED ADIPOSE TISSUE SURFACE.
- THE BLUE-INKED MUSCLE MARGIN OF RESECTION (SAID TO BE THE "TRUE" SURGICAL MARGIN AS PER [REDACTED] IS NEGATIVE FOR TUMOR.

NOTE: THE TUMOR CELLS ARE NEGATIVE FOR S-100 PROTEIN, CD34, EMA, , SMA, DESMIN AND
THEY ARE POSITIVE FOR FXIIIA. IMMUNOSTAINS FOR S-100 PROTEIN, CD34 AND
FXIIIA WERE PERFORMED ON BOTH HIGH GRADE CELLULAR AREAS OF PART 1 AND LESS
CELLULAR AREAS OF PART 2.

** Continued on next page **

ICD-O-3
Histocytoma, fibrous malignant
pleomorphic 8805/3
Site: Retroperitoneum C48.0
GJS 11/22/13

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 4 -----
ALTHOUGH THE ANATOMIC LOCATION OF THE TUMOR AND SOME MYXOID AND SCLEROSING
FEATURES SUGGEST THE POSSIBILITY OF A DEDIFFERENTIATED LIPOSARCOMA, MULTIPLE
SECTIONS OF PERITUMORAL ADIPOSE TISSUE FAIL TO REVEAL UNEQUIVOCAL FEATURES
OF A WELL DIFFERENTIATED ADIPOCYTIC NEOPLASM. THUS, IT SEEMS BEST NOT TO BE
DEFINITIVE, AND TO DESIGNATE THE TUMOR AS A PLEOMORPHIC HIGH GRADE SARCOMA,
NOS (WITH FEATURES, WHICH IN THE PAST WOULD HAVE BEEN CLASSIFIED AS
"MALIGNANT FIBROUS HISTIOCYTOMA").

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	S-100	
	NEG CONT	
	IMM RECUT	
	S-100	
	EMA	
	34BE12	
	CAM 5.2	
	SMA	
	FXIIia	
	NEG CONT	
	IMM RECUT	
	S-100	
	FXIIia	
	CD34	
	NEG CONT	
	IMM RECUT	

Gross Description:

1.) The specimen is received fresh labeled, "radical resection left retroperitoneal sarcoma" and consists of a left retroperitoneal dissection including left kidney and ureter, descending colon (including pericolic fat and a portion of omentum), left adrenal gland, and retroperitoneal fat. Within the retroperitoneal fat is a multilobated soft tissue mass which distorts normal anatomic relations within the retroperitoneum. Surgical margins are inked black. The two larger lobes of the mass measure 17.5 x 16.0 x 13.2 cm and 10.0 x 8.0 x 7.5 cm. Both lobes appear rounded in contour and well-circumscribed for the most part. Focally, the mass appears to extend irregularly into perirenal fat, through the kidney capsule and into the lower pole of the kidney, as well as into the muscularis of the descending colon. Medial to the descending colon, the mass has a hemorrhagic defect measuring 2.0 x 1.8 x 1.0 cm. Pericolic fat is adherent in this area. Sectioning through this mass reveals a firm tan-white nodular mass with extensive necrosis (approximately 60-70% of the larger nodule).

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 4

Focally, the mass has yellowish fatty areas and focally appears fleshy. The tumor extends to lateral, medial, anterior and posterior margins. The superior and inferior margins are grossly free of tumor. The portion of colon measures 47 cm in length, with a proximal margin circumference measuring 8.5 cm and a distal margin circumference of 5.0 cm. In its midportion, the bowel is adherent to the soft tissue mass, which invades the muscularis. The mucosa is unremarkable. Pericolic fat along the length of the colon measures up to 5 cm in thickness. Multiple lymph nodes are found within the fat. The omentum measures 20.0 x 14.0 x 2.0 cm. The left kidney measures 11.0 x 5.5 x 5.0 cm. The renal capsule is thickened and appears infiltrated as described above. A firm whitish circumscribed nodule penetrates to 2.0 cm into the kidney parenchyma. Sectioning of the kidney reveals otherwise unremarkable renal parenchyma. The ureter measures 20.0 by 0.5 cm. The ureter is separable from the mass by a tissue plane. The adrenal gland measures 5.0 x 2.0 x 1.5 cm. Sectioning reveals a hemorrhagic center. Located laterally with respect to the descending colon, is a portion of skeletal muscle measuring 6.0 x 1.8 x 1.0 cm. The specimen is photographed. Portions of tissue are submitted for possible future electron microscopy and for TPS.

Summary of sections:

UM - ureter margin
RVM - renal vascular margins
DCM - distal colon margin
PCM - proximal colon margin
A - adrenal gland
TK - tumor infiltrating kidney
TRC - thickened renal capsule
UK - unremarkable kidney
TCA - tumor infiltrating colon and anterior margin
SM - skeletal muscle and lateral margin
LM - tumor, lateral margin
MM - tumor, medial margin
PM - tumor, posterior margin
T - tumor
O - omentum
LN - pericolic lymph nodes

2.) The specimen is received fresh labeled, "final deep quadratus and psoas margin" and consists of multiple pieces of skeletal muscle and fibroadipose tissue measuring 15 x 8 x 3 cm in aggregate. The specimen is disrupted but appears to have a smooth surface and a rough surface, at one end. The roughened surface is inked blue and the smooth surface is inked black. Disrupted areas are not inked. Sectioning reveals unremarkable skeletal muscle and fibrofatty connective tissue. Representative sections submitted.

Summary of sections:

U -- undesignated.

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 4 of 4

Summary of Sections:

Part 1: SP: Radical resection left retroperitoneal sarcoma

Block	Sect.	Site	PCs
1	A		1
8	ADD		8
1	DCM		1
3	LM		3
2	LN		2
1	MM		1
2	O		2
1	PCM		1
1	PM		1
1	RVM		1
2	SM		2
8	T		8
1	TCA		1
2	TK		2
1	TRC		1
1	UK		1
1	UM		1

Part 2: SP: Final deep quadratus and psoas margin

Block	Sect.	Site	PCs
4	U		4

** End of Report **

Source: NCI Genomic Data Commons file 9b68172d-748c-4ec8-b456-c26ddae5b71b (TCGA-DX-A8BX.D35EC516-7383-403F-BEE8-8B02A4F2826B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).